Gene-level copy-number profile of tumor specimen TCGA-BR-8369-01A from TCGA case TCGA-BR-8369, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 76.8 years (28,051 days).
Specimen TCGA-BR-8369-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.779ebce6-728a-4dd2-a327-b9bf48701037.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8369-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1a4ca3e3-70be-4a3b-8a2e-60b9454404ff

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 893; copy number 2: 10,712; copy number 3: 18,092; copy number 4: 16,776; copy number 5: 8,479; copy number 6: 2,575; copy number 7: 553; copy number 8: 718; copy number 9: 17; copy number 10: 66; copy number 13: 16; copy number 14: 421; copy number 15: 40; copy number 16: 103; copy number 18: 6; copy number 21: 162; copy number 23: 76; copy number 30: 15; copy number 40: 92.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8369-01A-11D-2338-01): tumor purity 0.29, ploidy 3.34, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,285 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:134,932,889–145,098,174, 135 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr4:157,568,731–160,818,869, 44 genes, copy number 8–10: AC093817.2, LINC02433, AC093817.1, Y_RNA, AC017037.1, AC017037.3, AC017037.5, AC084740.1, AC017037.4, AC017037.2, AC098679.2, AC098679.3, GASK1B, FAM198B-AS1, AC098679.5, NUDT19P5, AC098679.1, TMEM144, AC098679.4, AIDAP2, RXFP1, RNU4-79P, AC121161.1, AC121161.2, C4orf46, ETFDH, U3, PPID, FNIP2, RNU6-128P, C4orf45, SNORD39, PSME2P3, FABP5P12, Y_RNA, RAPGEF2, MIR3688-1, MIR3688-2, AC074344.1, AC074344.2, LINC02233, AC093853.1, LINC02477, RPS14P7.
- chr4:167,648,430–173,530,229, 73 genes, copy number 8 (broad region; genes not listed).
- chr6:63,719,980–65,707,226, 1 gene, copy number 8 (within-gene range 4–8): EYS.
- chr6:64,377,795–66,728,904, 9 genes, copy number 8: AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P.
- chr8:1,565,509–19,084,730, 414 genes, copy number 10–23 (within-gene range 2–23) (broad region; genes not listed).
- chr8:81,791,823–145,066,685, 984 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr10:61,406,642–87,435,035, 484 genes, copy number 8–15 (within-gene range 2–15) (broad region; genes not listed).
- chr12:23,529,504–24,562,544, 1 gene, copy number 40 (within-gene range 2–40): SOX5.
- chr12:24,212,421–29,381,189, 106 genes, copy number 30–40 (broad region; genes not listed).
- chr21:31,118,416–32,728,040, 34 genes, copy number 8 (within-gene range 1–8): TIAM1, AP000248.1, AP000563.1, AP000251.1, FBXW11P1, AP000253.1, SOD1, AP000254.1, AP000254.2, SCAF4, HMGN1P2, AP000255.1, TPT1P1, HUNK, HUNK-AS1, LINC00159, AP000265.1, MIS18A, MIS18A-AS1, MRAP, MRAP-AS1, URB1, SNORA80A, URB1-AS1, CFAP298-TCP10L, EVA1C, EXOSC3P1, TCP10L, AP000272.1, RNA5SP490, CFAP298, OR7E23P, AP000275.1, SYNJ1.

Autosomal genes at a single copy (total copy number 1): 653. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
